Gene-level copy-number profile of tumor specimen TCGA-13-2061-01A from TCGA case TCGA-13-2061, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,543 days).
Specimen TCGA-13-2061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.608ac686-8da4-4ca4-937f-a4d23663be6d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-2061-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d7aef015-5e26-4e67-b457-d3190265ebaf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 787; copy number 2: 23,971; copy number 3: 12,973; copy number 4: 16,184; copy number 5: 3,305; copy number 6: 2,210; copy number 7: 114; copy number 8: 273.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-2061-01A-01D-1043-01): tumor purity 0.82, ploidy 2.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,902 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,466,249–78,017,964, 964 genes, copy number 5 (broad region; genes not listed).
- chr1:78,004,346–78,024,861, 2 genes, copy number 5: AC103591.3, AC103591.4.
- chr2:66,426,735–66,971,462, 9 genes, copy number 5–7 (within-gene range 3–7): MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628.
- chr2:218,419,121–218,597,080, 5 genes, copy number 5: VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P.
- chr3:68,975,217–69,542,583, 8 genes, copy number 6 (within-gene range 4–6): EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B.
- chr3:145,523,538–184,258,759, 611 genes, copy number 6 (broad region; genes not listed).
- chr3:184,259,213–184,261,553, 1 gene, copy number 6: CAMK2N2.
- chr6:167,607–41,736,259, 1,204 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:74,530,248–74,734,319, 1 gene, copy number 6 (within-gene range 4–6): AL356277.3.
- chr6:74,642,384–94,447,179, 258 genes, copy number 6 (broad region; genes not listed).
- chr7:151,341,699–159,233,377, 130 genes, copy number 5 (broad region; genes not listed).
- chr8:125,091,679–135,742,495, 141 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr8:137,105,352–138,497,261, 8 genes, copy number 5 (within-gene range 1–5): RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr10:44,712–38,762,491, 674 genes, copy number 5–6 (broad region; genes not listed).
- chr10:114,043,866–114,899,832, 20 genes, copy number 5 (within-gene range 4–5): ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1.
- chr11:39,024,631–39,261,213, 3 genes, copy number 6: AC021723.2, AC021723.1, RNU6-99P.
- chr11:65,066,300–65,695,837, 61 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:97,657,464–98,945,079, 7 genes, copy number 5: RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1.
- chr11:99,120,176–99,120,490, 1 gene, copy number 5: RN7SKP53.
- chr12:66,767–3,764,819, 92 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:132,725,503–133,214,832, 26 genes, copy number 6 (within-gene range 3–6): ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.
- chr13:22,915,651–23,325,162, 10 genes, copy number 5 (within-gene range 2–5): NUS1P2, AL157931.1, AL157931.2, HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4.
- chr13:73,054,976–73,113,018, 3 genes, copy number 5 (within-gene range 2–5): KLF5, FABP5P1, RNU6-66P.
- chr14:34,416,687–34,694,644, 14 genes, copy number 5: AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8.
- chr15:75,251,743–101,933,350, 694 genes, copy number 5 (broad region; genes not listed).
- chr16:10,627,501–10,694,930, 2 genes, copy number 5: TEKT5, AC007595.1.
- chr20:87,250–20,360,703, 386 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:46,859,333–46,864,104, 2 genes, copy number 6: RN7SKP33, AL354766.1.
- chr20:46,901,143–46,901,726, 1 gene, copy number 6: AL354766.2.
- chr20:57,488,392–64,313,132, 217 genes, copy number 6 (broad region; genes not listed).
- chr22:24,429,206–36,093,352, 347 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 784. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
